Surgical pathology report (de-identified scan), TCGA case TCGA-68-7756, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-7756-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

[REDACTED]

SPECIMEN SUBMITTED:

Part A: LEFT UPPER LOBE

Part B: LEVEL 5

Part C: LEVEL 6

Part D: LEVEL 7

Part E: LEVEL 9

Part F: LEVEL 10

Part G: LEVEL 11

Final Diagnosis

Left lung, upper lobe, lobectomy (A) - Adenosquamous carcinoma (see comment).

- Metastatic adenosquamous carcinoma in peribronchial lymph nodes.

- Centrilobular emphysema

2. Lymph nodes, level 5, level 6, level 7, level 9, level 11, excision (B-E, G) - Lymph nodes; negative for neoplasm

3. Lymph nodes, level 10, excision (F) - Microscopic focus of metastatic non-small cell carcinoma.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

Tumor Location: left upper lobe

Tumor Size: 3.6 x 3.4 x 2.9 cm

Vascular Invasion: extensively present.

Lymphatic Invasion: extensively present.

Bronchial Margin: negative

Vascular Margin: The tumor is present within the perivascular fibroadipose tissue at the pulmonary arterial margin.

Parenchymal Margins: not applicable.

Pleura/Soft Tissue Margin: The tumor invades through the visceral pleura and is present at the pleural adhesion margins.

Pathologic Stage (AJCC, 7th edition): p stage IIIA (T4 N1 MX).

Additional comments: The tumor is predominantly squamous cell carcinoma with areas of glandular formation and signet ring cells. Mucin stains (A6, A8, A11, A12) highlight the presence of intra and extracellular mucin. Immunohistochemical stains for TTF-1 and p-63 (blocks A8, A11, A4, A10) were used in the evaluation of this case. The adenocarcinoma component merge and mingle with the squamous cell carcinoma and represents approximately 5-10% of the tumor, consistent with adenosquamous type. EGFR mutation testing will be performed and the results reported as an addendum.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [REDACTED]
[REDACTED] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: ADDENDUM

Status: Signed Out

Text: This addendum is issued to report additional information. The tumor present in the perivascular soft tissue at the vascular margin section, is only within lymphovascular spaces, with no direct involvement of the fibroadipose tissue.

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Procedure: EGFR Mutation Analysis Re

Status: Signed Out

Text: EGFR Mutation Analysis

Diagnosis of neoplasm: No EGFR alteration detected

Genotype result: Wild type

Intraoperative Diagnosis:

{Not Entered}

Clinical Diagnosis:

LUL CA (NODULE)

STITCH MARKS WHERE TUMOR WAS ADHERENT TO CHEST WALL NEAR BYPASS GRAFT

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh labeled "left upper lobe" is a specimen that consists of an upper lobe of the left lung measuring 21.7 x 14.1 x 4.4 cm, and weighing 337.6 grams with the bronchial remnant that measures 1.2 cm in length. The pleural surface is pink-gray, roughened with an area of fibrous adhesions (inked black) which is overlying a poorly defined white-gray firm necrotic mass measuring 3.6 x 3.4 x 2.9 cm and invading and through the pleural surface and vessels grossly visible. The mass is 3.0 cm from the bronchial margin. The remainder of the lung tissue is unremarkable. Twelve nodules resembling lymph nodes are identified ranging from 0.7 to 2.0 cm in greatest dimension. Representative sections are submitted as follows: A1 bronchial margin, A2 vascular margin, A3-A10 mass (A3-A5 with pleural surface, A6-A8 with vascular involvement, A9 with bronchus, A11-A13 one possible lymph node, A14 four possible lymph nodes, A15 four possible lymph nodes, A16 three possible lymph nodes.

B. Received fresh labeled "level 5" are multiple irregular pink-black soft segments of tissue aggregating to 1.8 x 1.5 x 0.5 cm. The specimens are totally submitted in formalin in one cassette.

C. Received fresh labeled "level 6" are multiple irregular black soft segments of tissue aggregating to 1.2 x 0.7 x 0.4 cm. The specimens are totally submitted in formalin in one cassette.

D. Received fresh labeled "level 7" are multiple irregular black-yellow soft segments of tissue aggregating to 1.5 x 1.4 x 0.5 cm. The specimens are totally submitted in formalin in one cassette.

E. Received fresh labeled "level 9" is an irregular yellow segment of fibrofatty tissue measuring 2.2 x 0.7 x 0.5 cm. The specimen is totally submitted in formalin in one cassette.

F. Received fresh labeled "level 10" are multiple irregular black-pink soft segments of tissue aggregating to 1.5 x 1.3 x 0.4 cm. The specimens are totally submitted in formalin in one cassette.

G. Received fresh labeled "level 11" are multiple irregular black-pink soft segments of tissue aggregating to 1.5 x 1.0 x 0.4 cm. The specimens are totally submitted in formalin in one cassette.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file fbcffdf4-a951-473a-a4dc-42476bc37de0 (TCGA-68-7756.C358874D-3EF7-4361-AAAE-058B405619F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).